Somatic mutation profile of tumor specimen TCGA-HT-7676-01A (aliquot TCGA-HT-7676-01A-11D-2395-08) from TCGA case TCGA-HT-7676, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 26.5 years (9,667 days).
Specimen TCGA-HT-7676-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abe6a948-5209-46ad-9da9-c50939beae30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7676-10B (Blood Derived Normal), aliquot TCGA-HT-7676-10B-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae610f8f-2693-43eb-b3ef-501dc06c988e

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 30/75 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 58/70 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ETV5 | c.1259A>G p.D420G | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60500953; called by muse, mutect2, varscan2
- FER1L6 | c.4887G>T p.W1629C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67549246; called by muse, mutect2, varscan2
- KRT20 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1439265018, COSV51424526; called by muse, mutect2, varscan2
- PAPPA2 | c.4211C>T p.A1404V | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.303); catalogued as COSV62794747; called by muse, mutect2, varscan2
- PMEL | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756974126, COSV59385503; called by muse, mutect2, varscan2
- SEMA4B | c.1552G>A p.V518I | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as rs202078413; called by muse, mutect2, varscan2
- ZADH2 | c.1099G>A p.V367I | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV59268619; called by muse, mutect2, varscan2
- ZDHHC14 | c.553G>C p.D185H | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58193922; called by muse, mutect2
- ATRX | c.5757del p.M1920* | Frame Shift Del (DEL) | VAF 18/31 reads (58%) | called by mutect2, pindel, varscan2
- AHRR | c.600C>G p.L200= | Silent (SNP) | VAF 47/98 reads (48%) | catalogued as rs748917880, COSV57084626; called by muse, mutect2, varscan2
- CEP162 | c.1371A>G p.S457= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV57619075; called by muse, mutect2
- DDX51 | c.1698G>A p.A566= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as rs550340511, COSV57957399; called by muse, mutect2, varscan2
- OR13A1 | c.510C>T p.C170= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as rs759911354, COSV65572214; called by muse, mutect2, varscan2
- ZNF704 | c.849G>A p.T283= | Silent (SNP) | VAF 53/135 reads (39%) | catalogued as rs749536079, COSV59921938; called by muse, mutect2, varscan2
